Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A03L, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A03L-01A (Primary Tumor).

[page 1 of 4]
.....
Clinical Diagnosis & History:
T2 carcinoma right breast UOQ (core biopsy=invasive ductal carcinoma), for
right total mastectomy, SLNB, possible ALND.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla (fs) (
- 2: SP: Right modified radical mastectomy with levels 1 & 2 axillary
contents with tags attached

DIAGNOSIS:

- 1) SENTINEL LYMPH NODE #1, LEVEL I, RIGHT AXILLA; BIOPSY:
- METASTATIC CARCINOMA INVOLVING LYMPH NODE.
- 2) BREAST, RIGHT; MASTECTOMY WITH LEVELS I AND II AXILLARY CONTENTS:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT
OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND
SHAPE), MEASURING 6.5 CM IN LARGEST DIMENSION GROSSLY.
- THE INVASIVE CARCINOMA IS LOCATED IN THE CENTRAL AREA.
- THE NIPPLE LYMPHATICS ARE INVOLVED BY INVASIVE CARCINOMA.
- NO CALCIFICATIONS ARE IDENTIFIED IN THE INVASIVE CARCINOMA.
- EXTENSIVE VASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY INVASIVE CARCINOMA IS
IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE
LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL
I: 3/9; LEVEL II: 0/7.
- THERE IS NO EXTRANODAL EXTENSION OF CARCINOMA.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN
ADDENDUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

PATH
REPORT

** Continued on next page **

ICD-0-3
carcinoma, infiltrating duct, nos 8500/3
Site: breast, Nos C50.9
lw
10/21/11

[page 2 of 4]
Special Studies:
ResultSpecial Stain
ER-C
PR-C
HER2-C
NEG CONT
NEG-HER2
IMM RECUT

Comment

Gross Description:

, M.D.

, M.D.

1) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel node #1, level 1, right axilla". It consists of a 3.0 x 1.8 x 0.7 cm lymph node. Trisected and one section is submitted for frozen section. Cut section shows firm tan-white tissue. The remaining tissue is submitted as R. Entirely submitted.

Summary of Sections:

FSC frozen section control
R remaining lymph nodal tissue

M.D.

2) The specimen is received fresh, labeled, "Right modified radical mastectomy with levels 1 & 2 axillary contents with tags attached". It consists of a product of modified radical mastectomy, breast measuring 16.0 x 11.5 x 5.0 cm with attached axillary tissue, measuring 7.9 x 7.0 x 2.0 cm with tags attached labeled one and two. Anteriorly, the skin ellipse measures 9.2 x 1.5 cm bearing an unremarkable nipple and areola. The epidermal surface is unremarkable, except for blue dye staining. Serially sectioned from medial to lateral aspect. Cut section shows a 6.5 x 4.0 x 2.5 cm tumor, located in the central quadrant, about 1.5 cm beneath the overlying skin and 0.2 cm from the deep resection margin. The cut section of the tumor has firm, tan-pink tissue with focal areas of hemorrhage. The adjacent breast tissue is predominantly fatty with scattered fibrous streaks. No other satellite nodules are seen. Representative sections from the tumor and the other quadrants are submitted. Part of tissue is submitted for TPS. Multiple lymph nodes are dissected from the axillary tissue from levels one and two, size ranging from 0.5 cm to 1.5 x 1.0 x 1.0 cm. The larger lymph nodes are bisected. The specimen is inked as follows: superior-blue, inferior-red, posterior-black.

Summary of Sections:

N entirely submitted nipple and areola
T tumor
TM tumor to margin
C central quadrant, two sections
UOQ upper outer quadrant, two sections
LOQ lower outer quadrant, two sections
UIQ upper inner quadrant, two sections

PATH
REPORT

** Continued on next page **

[page 3 of 4]
LIQ lower inner quadrant, two sections
L1LN level one lymph nodes
L2LN level two lymph nodes
L1BLN level one bisected lymph nodes

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, right axilla (fs)

Block	Sect.	Site	PCs
1		FSC	1
3		R	3

Part 2: SP: Right modified radical mastectomy with levels 1 & 2 axillary contents with tags attached

Block	Sect.	Site	PCs
1		C	2
1		L1BLN	2
1		L1LN	6
2		L2LN	12
3		LIQ	2
1		LOQ	2
1		N	2
2		T	2
2		TM	4
4		UIQ	2
2		UOQ	2
1			

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

By:

Date Reported:

Addendum Diagnosis
ADDENDUM

SITE: RIGHT BREAST
PART #2.

ER: 70% OF NUCLEAR STAINING WITH MODERATE INTENSITY.
PR: 10% OF NUCLEAR STAINING WITH MODERATE INTENSITY

HER2/NEU (HERCEPT): POSITIVE (STAINING INTENSITY OF 2+).

PATH
REPORT

** Continued on next page **

[page 4 of 4]
MD PHD

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

MD

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file a9c23cdf-b314-4c88-89aa-ef58933bd073 (TCGA-AO-A03L.FF7212E5-9A44-4659-B3B9-3EF2DB7A9E6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).